Somatic mutation profile of tumor specimen TCGA-E1-A7YL-01A (aliquot TCGA-E1-A7YL-01A-11D-A34A-08) from TCGA case TCGA-E1-A7YL, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 46.5 years (16,982 days).
Specimen TCGA-E1-A7YL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b864ef2c-5d59-45e8-b12f-f978da61af47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YL-10A (Blood Derived Normal), aliquot TCGA-E1-A7YL-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3387fd2-47e7-4c2d-881c-1d15af85e53a

The open-access MAF lists 56 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 12, Nonsense Mutation 2, Frame Shift Del 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.393G>C p.W131C | Missense Mutation (SNP) | VAF 36/140 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV61653780, COSV61655224; called by muse, mutect2, varscan2
- TP53 | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs1057520008, CD100447, COSV52760580, COSV52806341, COSV52877975, COSV52979708; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TP53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.4004G>A p.R1335H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs756671698, COSV100750470; called by muse, mutect2, varscan2
- ACAN | c.2687C>A p.S896Y | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100716872; called by muse, mutect2, varscan2
- ACE | c.2327C>T p.T776M | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs769940023, COSV99326264; called by muse, mutect2, varscan2
- ANKRD55 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs757942486, COSV100590995; called by muse, mutect2, varscan2
- ATP2B2 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100659505; called by muse, mutect2, varscan2
- CARMIL1 | c.3364C>T p.R1122W | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.591); catalogued as rs568931456, COSV61517161; called by muse, mutect2, varscan2
- CDYL2 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV101629494; called by muse, mutect2, varscan2
- DNAH11 | c.11674A>G p.M3892V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs72658813, COSV100176496; called by muse, mutect2, varscan2
- FAT2 | c.10555G>C p.V3519L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV99941457; called by muse, mutect2, varscan2
- FMN1 | c.2915G>A p.R972Q (on ENST00000616417 / NM_001277313.2; = p.R749Q on NM_001103184.4) | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs772848712, COSV57936199; called by muse, mutect2, varscan2
- GAB2 | c.460C>T p.R154* (on ENST00000361507 / NM_080491.3; = p.R116* on NM_012296.3) | Nonsense Mutation (SNP) | VAF 33/84 reads (39%) | catalogued as rs1430811581, COSV60871626; called by muse, mutect2, varscan2
- GSDMC | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.049); catalogued as rs910419404, COSV52692967; called by muse, mutect2, varscan2
- HK2 | c.2039C>T p.T680M | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138539339; called by muse, mutect2, varscan2
- ITSN1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750087030, COSV66082829; called by mutect2, varscan2
- KIF16B | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100733648, COSV61704744; called by muse, mutect2, varscan2
- KIT | c.1299C>A p.F433L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV99852938; called by muse, mutect2, varscan2
- MANBA | c.1607G>C p.R536T (on ENST00000642252; = p.R490T on NM_005908.4) | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV99898214; called by muse, mutect2, varscan2
- MC3R | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552943206, COSV54763275; called by muse, mutect2, varscan2
- MLLT10 | c.2744C>T p.A915V (on ENST00000307729 / NM_001195626.3; = p.A931V on NM_004641.3) | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV100307283; called by muse, mutect2, varscan2
- MRPS21 | c.16A>C p.K6Q | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV100481621; called by muse, mutect2, varscan2
- MYF6 | c.62C>A p.T21N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.287); catalogued as COSV99952632; called by muse, mutect2, varscan2
- MYH8 | c.1756G>T p.A586S | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs1363791536, COSV101238086; called by muse, mutect2, varscan2
- NLRP4 | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149428225; called by muse, mutect2, varscan2
- NRDC | c.3001G>C p.E1001Q | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.289); catalogued as COSV100542822; called by muse, mutect2, varscan2
- OR5M8 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs201389871; called by muse, mutect2, varscan2
- PLOD2 | c.1446T>G p.F482L | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV99282250; called by muse, mutect2, varscan2
- PTPN22 | c.1529G>A p.R510H (on ENST00000359785 / NM_001193431.2; = p.R455H on NM_012411.5) | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs202143877, COSV100703348; called by muse, mutect2, varscan2
- RUNDC3A | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs866738146, COSV99841674; called by muse, mutect2
- SCARA5 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1472054381, COSV100107588; called by muse, mutect2, varscan2
- SOX30 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV53937377, COSV53939850; called by muse, mutect2, varscan2
- TBC1D2B | c.2326G>A p.V776I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs138371601; called by muse, varscan2
- TBX21 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99455812; called by muse, mutect2, varscan2
- TMEM132B | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs781241046, COSV54769432; called by muse, mutect2, varscan2
- TTN | c.19191C>A p.Y6397* (on ENST00000591111; = p.Y5470* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100591502; called by muse, mutect2, varscan2
- VPS13B | c.4218C>G p.D1406E | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.012); catalogued as COSV100660644; called by muse, mutect2, varscan2
- ZNF526 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766433660, COSV99725032; called by muse, mutect2, varscan2
- ZSCAN18 | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV99559008; called by muse, mutect2, varscan2
- SPRY2 | c.889_892del p.N297Qfs*57 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- ZNF608 | c.3787_3790del p.E1263Rfs*3 | Frame Shift Del (DEL) | VAF 36/103 reads (35%) | called by mutect2, pindel, varscan2
- ACTL9 | c.126C>T p.A42= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs1555753525, COSV61007002; called by muse, mutect2, varscan2
- ADAM28 | c.1620G>A p.K540= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99737535; called by muse, mutect2, varscan2
- CACNA1D | c.2712C>T p.A904= (on ENST00000350061 / NM_001128840.3; = p.A924= on NM_000720.4) | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as rs148699423; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC144A | c.63C>T p.Y21= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV61403024; called by muse, mutect2, varscan2
- ERCC6 | c.3825C>T p.A1275= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100875604; called by muse, mutect2, varscan2
- LENG9 | c.633G>T p.L211= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV100002641; called by muse, mutect2, varscan2
- NRDC | c.2826G>T p.L942= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as COSV100702990; called by muse, mutect2, varscan2
- NUTM1 | c.1464C>T p.G488= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs759270034, COSV59217693; called by muse, mutect2, varscan2
- OR2T12 | c.660C>T p.L220= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs1473316901, COSV100527483, COSV58777869; called by muse, mutect2, varscan2
- PCDHGA7 | c.1476C>T p.A492= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs190245807; called by muse, mutect2, varscan2
- SHANK2 | c.4755G>A p.P1585= | Silent (SNP) | VAF 54/102 reads (53%) | catalogued as rs144792130, COSV99571854; called by muse, mutect2, varscan2
- TRIT1 | c.615T>C p.R205= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV57547085; called by muse, mutect2, varscan2
- DCHS2 | n.7078_7081del | RNA (DEL) | VAF 17/104 reads (16%) | called by pindel, varscan2
- ST6GALNAC6 | c.*193_*195del | 3'UTR (DEL) | VAF 16/64 reads (25%) | called by pindel, varscan2
